Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040027-09A.2 (aliquot TARGET-15-SJMPAL040027-09A.2-01D) from TARGET case TARGET-15-SJMPAL040027, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,657 days).
Specimen TARGET-15-SJMPAL040027-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 851cea2e-9957-43be-ab25-3b6039ac4878.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040027-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040027-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7d3c692-73af-4a91-9283-428fb3c6cb16

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 116/122 reads (95%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, varscan2
- CPT1B | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs368302579; called by muse, mutect2, varscan2
- GLYAT | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1565053353; called by muse, mutect2, varscan2
- PCDH9 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117947; called by muse, mutect2
- RHOD | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs749309126; called by muse, varscan2
- DHX57 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXT1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- KIF1A | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPAR4 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2
- USP9X | c.2878-2A>C p.X960_splice | Splice Site (SNP) | VAF 24/26 reads (92%) | called by muse, mutect2
- VPS51 | c.1682T>G p.V561G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF57 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAMTS18 | c.1473G>A p.A491= | Silent (SNP) | VAF 96/185 reads (52%) | catalogued as rs148669189, COSV51400093; called by muse, mutect2, varscan2
- EFCAB6 | c.4068C>T p.N1356= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- PCDHA11 | c.123C>T p.H41= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as rs1428940405, COSV56551586; called by muse, mutect2, varscan2
- TUBA3C | c.717G>A p.T239= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as rs397839852; called by muse, mutect2, varscan2
